Somatic mutation profile of tumor specimen TCGA-36-2551-01A (aliquot TCGA-36-2551-01A-01D-1526-09) from TCGA case TCGA-36-2551, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.6 years (21,045 days).
Specimen TCGA-36-2551-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d4f2b68-f501-4ae2-b05a-4b771c7056e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2551-10A (Blood Derived Normal), aliquot TCGA-36-2551-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04ca1bc7-4e17-4dd7-9f86-4cfbc6af5a6c

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 13, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 310/375 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.1362T>A p.H454Q | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.864); catalogued as COSV62415663; called by muse, mutect2, varscan2
- C12orf60 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57451613; called by muse, mutect2, varscan2
- CLIP3 | c.1078A>T p.I360F | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV53324380; called by muse, mutect2, varscan2
- DENND2C | c.2684G>A p.R895Q (on ENST00000393274 / NM_001256404.2; = p.R838Q on NM_198459.4) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1353554902, COSV67921048; called by muse, mutect2, varscan2
- DNM2 | c.2171G>A p.R724H (on ENST00000355667 / NM_001005360.3; = p.R720H on NM_004945.3) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1160341992, COSV53033495; called by muse, mutect2, varscan2
- EIF5A2 | c.136T>G p.S46A | Missense Mutation (SNP) | VAF 61/996 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99858828; called by muse, mutect2
- ENAH | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV52866885; called by muse, mutect2, varscan2
- GAK | c.181G>C p.G61R | Missense Mutation (SNP) | VAF 84/464 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58503884; called by muse, mutect2, varscan2
- GNL1 | c.1687T>C p.S563P | Missense Mutation (SNP) | VAF 84/423 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.969); catalogued as COSV64920905; called by muse, mutect2, varscan2
- HSD17B14 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54413029; called by muse, mutect2, varscan2
- KCNJ4 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs768019896, COSV57856702; called by muse, mutect2, varscan2
- LRRC7 | c.1532C>T p.A511V (on ENST00000651989 / NM_001370785.2; = p.A478V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV50499900; called by muse, mutect2, varscan2
- NLGN1 | c.1025T>A p.L342H | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64328993; called by muse, mutect2, varscan2
- RCOR3 | c.843G>A p.E281= | Splice Region (SNP) | VAF 19/110 reads (17%) | catalogued as COSV65365414, COSV65367249; called by muse, mutect2, varscan2
- RNF207 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.438); catalogued as COSV65007411; called by muse, mutect2, varscan2
- SNX20 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs376792548, COSV56057222; called by muse, mutect2, varscan2
- VPS37C | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57108400; called by muse, mutect2, varscan2
- WWTR1 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 67/492 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV62291005; called by muse, mutect2, varscan2
- ZC3H7B | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs762631126, COSV60961365; called by muse, mutect2, varscan2
- ZNF324B | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100351788, COSV60743415; called by muse, mutect2
- ZNF565 | c.754C>T p.Q252* (on ENST00000355114; = p.Q212* on NM_152477.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/290 reads (9%) | catalogued as COSV100411994; called by muse, mutect2
- TOMM40L | c.173_176dup p.H59Qfs*35 | Frame Shift Ins (INS) | VAF 41/266 reads (15%) | called by mutect2, pindel, varscan2
- DLG5 | c.3927C>T p.I1309= | Silent (SNP) | VAF 124/352 reads (35%) | catalogued as rs1001759227, COSV64947520; called by muse, mutect2, varscan2
- KCTD18 | c.1071G>A p.T357= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs569262259, COSV63344126; called by muse, mutect2, varscan2
- LONP1 | c.738G>A p.A246= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs1035298522, COSV62261248; called by muse, mutect2, varscan2
- MRPL28 | c.621G>A p.T207= | Silent (SNP) | VAF 82/130 reads (63%) | catalogued as rs113936863; called by muse, mutect2, varscan2
- NAF1 | c.723C>T p.F241= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs780245066, COSV56803934; called by muse, mutect2, varscan2
- PCDHA3 | c.507T>G p.T169= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV65366147; called by muse, mutect2, varscan2
- RBM25 | c.474C>T p.L158= | Silent (SNP) | VAF 68/340 reads (20%) | catalogued as rs1281266093, COSV56199438; called by muse, mutect2, varscan2
- SCAF4 | c.1788A>G p.E596= | Silent (SNP) | VAF 46/466 reads (10%) | catalogued as COSV99742097; called by muse, mutect2
- SMAD2 | c.633G>A p.E211= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as COSV50995679; called by muse, mutect2, varscan2
- ST18 | c.2932C>T p.L978= | Silent (SNP) | VAF 148/837 reads (18%) | catalogued as COSV52490131; called by muse, mutect2, varscan2
- XRCC1 | c.174G>A p.V58= | Silent (SNP) | VAF 148/752 reads (20%) | catalogued as COSV53448550; called by muse, varscan2
- ZIC1 | c.804T>C p.N268= | Silent (SNP) | VAF 65/480 reads (14%) | catalogued as rs753755493, COSV51552360; called by muse, mutect2, varscan2
- ZMIZ1 | c.2964G>A p.Q988= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV57893096; called by muse, mutect2, varscan2
- ATAD3B | c.*435C>T | 3'UTR (SNP) | VAF 64/150 reads (43%) | catalogued as rs370500078, COSV100426601; called by muse, mutect2, varscan2
